Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WL, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WL-01A (Primary Tumor).

Gross:

Ovoid tumor with fibrous capsule (130x100x90 mm, 640 g), on cut brown-yellow, spotted.

Material was procured in 6 blocks

Micro: Diffusely and solidly alveolarly shaped pheochromocytoma (right) formed from large polygonal, focally spindle-shaped and somewhere else bizarre cells with hyperchromatic nuclei, with focal fibrotisation (trichrome) and with lymphoplasmacellular infiltration, with signs of fresh and old hemorrhage (Fe).

Nor invasion neither into vessels, nor through capsule was found, surrounding adipose tissue was not available for evaluation. In central part of the tumor, large foci of scarring were found.

Immunohistochemic examination:

Staining for S100 protein negative – sustentacular cells are missed.

MIB1 <1% positive nuclei.

Congo red negative.

PASS:

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis

High cellularity

Cellular monotony

Tumor cell spindling (even if focal) 2

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 6

Procurement date:

Confirmation date:

ICD-O-3
Pheochromocytoma, malignant
8760/3

Site: Adrenal gland NOS
C74.9

9/10/9/13

Source: NCI Genomic Data Commons file 62db600a-51b3-4c5b-baf3-d464b6de2c23 (TCGA-S7-A7WL.2E78E513-E9BE-4E78-8A4D-1507803862A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).